Somatic mutation profile of tumor specimen C3N-03229-02 (aliquot CPT0180240006) from CPTAC case C3N-03229, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 75.8 years (27,702 days).
Specimen C3N-03229-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f213f28e-fc16-452d-99f2-9287364c6fd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03229-71 (Blood Derived Normal), aliquot CPT0180350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7285037-4488-4101-bb82-38319182c992

The open-access MAF lists 4,428 somatic variants for this specimen: 2,775 protein-altering or splice-affecting, 1,474 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,548, Silent 1,474, Nonsense Mutation 158, Intron 97, Splice Region 28, 3'UTR 21, Splice Site 21, 5'Flank 19, 5'UTR 18, RNA 17, Frame Shift Del 11, 3'Flank 7.

Variants (750 of 4,428; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.2311C>T p.P771S (on ENST00000288602 / NM_001374244.1; = p.P731S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562931107, COSV56058484; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PRPH2 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 117/534 reads (22%) | catalogued as rs61755771, CM930635, COSV57837088; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 54/149 reads (36%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RIPPLY2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 46/224 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100859440, COSV63746041; called by muse, mutect2, varscan2
- TJP2 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 101/320 reads (32%) | catalogued as rs746830415, COSV55265049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 94/255 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1052933001; called by muse, mutect2, varscan2
- AADACL2 | c.87A>T p.E29D | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV100735682; called by muse, varscan2
- AARS1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1040693054; called by muse, mutect2, varscan2
- ABCA12 | c.3679G>A p.E1227K (on ENST00000272895 / NM_173076.3; = p.E909K on NM_015657.3) | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286289900; called by muse, mutect2, varscan2
- ABCA13 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546968040; called by muse, mutect2, varscan2
- ABCB5 | c.2840G>A p.G947E (on ENST00000404938 / NM_001163941.2; = p.G502E on NM_178559.6) | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.54); catalogued as COSV51712327; called by muse, mutect2
- ABCC12 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs909331610; called by muse, mutect2, varscan2
- ABCC9 | c.2022C>T p.V674= | Splice Region (SNP) | VAF 48/203 reads (24%) | catalogued as rs1555195612; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCE1 | c.1361T>A p.I454N | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1448769122; called by muse, mutect2, varscan2
- ABCG2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs144647749; called by muse, mutect2, varscan2
- AC092835.1 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs866438666; called by muse, mutect2, varscan2
- ACACB | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762611929; called by muse, mutect2, varscan2
- ACAN | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 129/663 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1213712769; called by muse, mutect2, varscan2
- ACBD6 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 51/310 reads (16%) | catalogued as rs771552233; called by muse, mutect2, varscan2
- ACCSL | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV66582701; called by muse, mutect2, varscan2
- ACOXL | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV101093737; called by muse, mutect2, varscan2
- ACP4 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 127/527 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567824; called by muse, mutect2, varscan2
- ACSBG1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1046002792; called by muse, mutect2, varscan2
- ACSM1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV54633527; called by muse, mutect2, varscan2
- ACSM2A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV54585410; called by muse, mutect2, varscan2
- ACSM4 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 53/193 reads (27%) | catalogued as COSV68069329; called by muse, mutect2, varscan2
- ACSM4 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV68067400; called by muse, mutect2, varscan2
- ACSM4 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV68069413; called by muse, mutect2, varscan2
- ACSS3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1247209581, COSV54084933; called by muse, mutect2, varscan2
- ACTC1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV51760420; called by muse, mutect2, varscan2
- ADAD2 | c.421C>T p.P141S (on ENST00000315906 / NM_001145400.2; = p.P213S on NM_139174.4) | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs1040258914; called by muse, mutect2, varscan2
- ADAD2 | c.566C>T p.P189L (on ENST00000315906 / NM_001145400.2; = p.P261L on NM_139174.4) | Missense Mutation (SNP) | VAF 114/392 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs777502357; called by mutect2, varscan2
- ADAM2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.048); catalogued as rs1159310623; called by muse, mutect2, varscan2
- ADAM20 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV56454255; called by muse, varscan2
- ADAM28 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV56098550; called by muse, mutect2, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by muse, mutect2, varscan2
- ADAM30 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs762560432, COSV65561010; called by muse, mutect2, varscan2
- ADAM33 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1343276329; called by muse, mutect2, varscan2
- ADAM7 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV51546060; called by muse, mutect2, varscan2
- ADAM8 | c.639C>T p.F213= | Splice Region (SNP) | VAF 92/254 reads (36%) | catalogued as COSV69864711; called by muse, mutect2, varscan2
- ADAMDEC1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976542769, COSV99835917; called by muse, mutect2, varscan2
- ADAMTS12 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV61263232, COSV61272776; called by muse, mutect2, varscan2
- ADAMTS18 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs144292157; called by muse, varscan2
- ADAMTS20 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV101240329; called by muse, mutect2, varscan2
- ADAMTS20 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67126043; called by muse, mutect2, varscan2
- ADAMTS9 | c.3896C>T p.T1299I | Missense Mutation (SNP) | VAF 159/536 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs760531652; called by muse, mutect2, varscan2
- ADAMTS9 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV55789955; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2819C>T p.S940L | Missense Mutation (SNP) | VAF 142/404 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as rs1340218977, COSV65892530; called by muse, mutect2, varscan2
- ADCY10 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63238889; called by muse, mutect2, varscan2
- ADGB | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV58864807; called by muse, mutect2, varscan2
- ADGRB3 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs573044070, COSV65401208; called by muse, mutect2, varscan2
- ADGRB3 | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235107, COSV53241518; called by muse, mutect2, varscan2
- ADGRF3 | c.2767G>A p.G923R (on ENST00000311519 / NM_001145168.1; = p.G724R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/506 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV61048680; called by muse, varscan2
- ADGRF3 | c.2746G>A p.E916K (on ENST00000311519 / NM_001145168.1; = p.E717K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/541 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV61048992; called by muse, varscan2
- ADGRF4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 193/466 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, mutect2, varscan2
- ADGRL2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746200328, COSV54660115; called by muse, mutect2, varscan2
- ADGRL4 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs754785225, COSV100875502; called by muse, mutect2, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, varscan2
- ADH6 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1274691731, COSV52955220; called by muse, mutect2, varscan2
- ADIPOR1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs1485692750, COSV61851133; called by muse, varscan2
- AFM | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867565889, COSV56921393; called by muse, mutect2, varscan2
- AGBL2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs370614257; called by muse, mutect2, varscan2
- AGTR1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100837048; called by muse, mutect2, varscan2
- AHNAK | c.14297C>T p.T4766I | Missense Mutation (SNP) | VAF 164/414 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1224441429, COSV99949603; called by muse, mutect2, varscan2
- AK5 | c.586G>A p.E196K (on ENST00000354567 / NM_174858.3; = p.E170K on NM_012093.4) | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV58355416; called by muse, mutect2, varscan2
- AK5 | c.742C>T p.Q248* (on ENST00000354567 / NM_174858.3; = p.Q222* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 117/354 reads (33%) | catalogued as COSV60980125, COSV60980774; called by muse, mutect2, varscan2
- AK5 | c.1414G>A p.E472K (on ENST00000354567 / NM_174858.3; = p.E446K on NM_012093.4) | Missense Mutation (SNP) | VAF 133/344 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV60968300, COSV60971368; called by muse, mutect2, varscan2
- AKAP6 | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55210022; called by muse, mutect2, varscan2
- AKNAD1 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.272); catalogued as COSV100645520; called by muse, mutect2, varscan2
- AL121899.2 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 107/408 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs865858082; called by muse, mutect2, varscan2
- AL592490.1 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 114/304 reads (38%) | catalogued as COSV69424679; called by muse, mutect2, varscan2
- ALDH1L1 | c.1977G>A p.M659I | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs267599591, COSV56418439; called by muse, mutect2, varscan2
- ALG10B | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1297001069; called by muse, mutect2
- ALOX15B | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1043933934, COSV66479972; called by muse, mutect2, varscan2
- AMY1A | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 106/349 reads (30%) | catalogued as COSV64410921; called by muse, mutect2, varscan2
- AMY1C | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 44/518 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs754760174; called by muse, mutect2, varscan2
- ANGPT1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs867964520, COSV52431619, COSV99864298; called by muse, mutect2
- ANGPTL4 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 116/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569902721; called by muse, mutect2, varscan2
- ANGPTL5 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212631602; called by muse, mutect2, varscan2
- ANK1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs907775044, COSV55877464; called by muse, mutect2, varscan2
- ANK3 | c.10942G>A p.E3648K | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs761370414, COSV55065631; called by muse, varscan2
- ANKFN1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1244037287, COSV59439891; called by muse, mutect2, varscan2
- ANKLE1 | c.1202G>A p.R401K (on ENST00000394458; = p.R347K on NM_152363.6) | Missense Mutation (SNP) | VAF 124/497 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV63921707; called by muse, mutect2, varscan2
- ANKMY1 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 89/385 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV56037251; called by muse, mutect2, varscan2
- ANKRD18B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1234074751; called by muse, mutect2, varscan2
- ANKRD24 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs1320560344; called by muse, mutect2, varscan2
- ANKRD24 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 177/659 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs780679171; called by muse, mutect2
- ANKRD30A | c.1426G>A p.E476K (on ENST00000611781; = p.E420K on NM_052997.2) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs867286949, COSV64607688; called by muse, mutect2, varscan2
- ANKRD30B | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.982); catalogued as rs762249858; called by muse, mutect2, varscan2
- ANKRD42 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV99035973; called by muse, mutect2, varscan2
- ANKRD63 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 118/452 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.301); catalogued as rs1353607465; called by muse, mutect2, varscan2
- ANO2 | c.735G>A p.M245I (on ENST00000356134 / NM_001278597.3; = p.M249I on NM_001278596.3) | Missense Mutation (SNP) | VAF 98/341 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV59023604; called by muse, mutect2, varscan2
- ANO4 | c.899G>A p.G300E (on ENST00000392977 / NM_001286615.2; = p.G265E on NM_178826.4) | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as COSV54612507; called by muse, mutect2, varscan2
- ANO7 | c.608C>T p.S203L (on ENST00000274979; = p.S149L on NM_001370694.2) | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs201908062; called by muse, mutect2, varscan2
- ANOS1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 141/266 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs751668763, CM050277, CM167093, COSV52917011; called by muse, mutect2, varscan2
- AOC1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 110/451 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766897897; called by mutect2, varscan2
- AOX1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65983758; called by muse, mutect2, varscan2
- AOX1 | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV53496638; called by muse, mutect2, varscan2
- AP1M1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs376335032; called by muse, mutect2, varscan2
- AP2A2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100173390; called by muse, mutect2, varscan2
- APBA3 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 122/476 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs868772901, COSV99516390; called by muse, mutect2, varscan2
- APBB1IP | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100881997; called by muse, mutect2, varscan2
- APOB | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 132/436 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51940164, COSV99267469; called by muse, mutect2, varscan2
- AQP4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV67219488; called by muse, mutect2, varscan2
- ARFGEF3 | c.6475C>T p.R2159C | Missense Mutation (SNP) | VAF 121/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776499591, COSV52462151; called by muse, mutect2, varscan2
- ARHGAP22 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 145/522 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779541553; called by muse, mutect2, varscan2
- ARHGEF33 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs377504175; called by muse, mutect2, varscan2
- ARHGEF5 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1255390988; called by muse, varscan2
- ARIH1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV65912837; called by muse, mutect2, varscan2
- ARMC4 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 99/342 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV59471571; called by muse, mutect2, varscan2
- ARMC4 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 40/233 reads (17%) | catalogued as COSV59475161; called by muse, mutect2, varscan2
- ARPP21 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.991); catalogued as rs1209804946; called by muse, mutect2, varscan2
- ART1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 152/566 reads (27%) | catalogued as rs1308334286; called by muse, mutect2, varscan2
- ASB17 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99408047; called by muse, mutect2, varscan2
- ASH1L | c.7990C>T p.R2664C (on ENST00000368346 / NM_001366177.2; = p.R2659C on NM_018489.3) | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs369466292; called by muse, varscan2
- ASTN1 | c.3647G>A p.R1216K | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99054539; called by muse, mutect2, varscan2
- ASXL3 | c.3954G>A p.M1318I | Missense Mutation (SNP) | VAF 55/349 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1228453782, COSV99327093; called by muse, mutect2, varscan2
- ASZ1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs778822842, COSV104372633; called by muse, mutect2, varscan2
- ATF6B | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 291/633 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100916847; called by muse, mutect2, varscan2
- ATP10B | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs964794391; called by muse, mutect2, varscan2
- ATP10D | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 92/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770384605, COSV56708390; called by muse, mutect2, varscan2
- ATP13A3 | c.3526C>T p.R1176* | Nonsense Mutation (SNP) | VAF 81/304 reads (27%) | catalogued as rs1376912188, COSV55468231; called by muse, mutect2, varscan2
- ATP1B4 | c.586G>A p.E196K (on ENST00000218008 / NM_001142447.3; = p.E192K on NM_012069.5) | Missense Mutation (SNP) | VAF 111/175 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.191); catalogued as rs894682183, COSV54311905; called by muse, mutect2, varscan2
- ATP2A1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs748538818; called by muse, mutect2, varscan2
- ATP2A2 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100428784; called by muse, mutect2, varscan2
- ATP2B1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53808011, COSV53815055; called by muse, mutect2, varscan2
- ATP8B4 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs569305697, COSV52725371; called by muse, varscan2
- ATP9A | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58764914; called by muse, mutect2, varscan2
- ATR | c.3685G>T p.E1229* | Nonsense Mutation (SNP) | VAF 64/285 reads (22%) | catalogued as COSV63386265; called by muse, mutect2, varscan2
- ATRAID | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 95/495 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1417563010; called by muse, mutect2, varscan2
- ATXN1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 148/555 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV55216835, COSV55230747; called by muse, mutect2, varscan2
- ATXN7L1 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 169/623 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1338449133; called by muse, mutect2, varscan2
- AXIN1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 148/599 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1460653989, COSV51992545; called by muse, mutect2, varscan2
- B3GNT4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV57336900; called by muse, mutect2
- B4GALNT2 | c.1454G>A p.R485K | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV55925689; called by muse, varscan2
- BACE2 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1253241997; called by muse, mutect2, varscan2
- BAHCC1 | c.6512C>T p.P2171L | Missense Mutation (SNP) | VAF 139/485 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555659121, COSV57031188; called by muse, mutect2, varscan2
- BAP1 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs369259771, CM160683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BASP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 144/469 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1478735559, COSV100493739; called by muse, mutect2, varscan2
- BAZ2A | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51631810, COSV99467239; called by muse, mutect2, varscan2
- BCLAF1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750013043, COSV62144372, COSV62145602; called by muse, mutect2, varscan2
- BMP10 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs377139113; called by muse, mutect2, varscan2
- BMP15 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1557280278; called by muse, mutect2, varscan2
- BMPER | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448830241; called by muse, mutect2, varscan2
- BPI | c.772G>A p.E258K (on ENST00000262865; = p.E254K on NM_001725.3) | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53407454; called by muse, mutect2, varscan2
- BRAF | c.1916C>A p.T639K (on ENST00000288602 / NM_001374244.1; = p.T599K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as CM086780, COSV56072224, COSV56167356; called by muse, mutect2, varscan2
- BRINP3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV100819139, COSV66537342; called by muse, mutect2, varscan2
- C10orf71 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV60512630; called by muse, mutect2, varscan2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 81/343 reads (24%) | catalogued as rs761345073; called by mutect2, pindel*, varscan2
- C14orf39 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100407844, COSV58780571; called by muse, mutect2, varscan2
- C16orf89 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs532111292, COSV100280997; called by muse, mutect2, varscan2
- C1QTNF9B | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 117/556 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221459808, COSV101158611; called by muse, mutect2, varscan2
- C2CD6 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs747787691; called by muse, mutect2, varscan2
- C2orf78 | c.2651G>A p.R884K | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs756025346, COSV101280906, COSV68519290; called by muse, mutect2, varscan2
- C3 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55573420; called by muse, mutect2, varscan2
- C4BPA | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 69/348 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV65536075; called by muse, mutect2, varscan2
- C6 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV54705990; called by muse, mutect2, varscan2
- C6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV54720835; called by muse, mutect2, varscan2
- C6orf132 | c.2489G>A p.G830E | Missense Mutation (SNP) | VAF 136/665 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1444617937; called by muse, mutect2, varscan2
- C7orf31 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV52219991; called by muse, mutect2, varscan2
- C7orf33 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV61023437; called by muse, mutect2, varscan2
- C8B | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1360423598; called by muse, mutect2, varscan2
- C9orf152 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV101272372; called by muse, mutect2, varscan2
- CACNA1A | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 132/536 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as rs752824390, COSV64197936; called by muse, mutect2, varscan2
- CACNA1C | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59717806; called by muse, mutect2, varscan2
- CACNA1C | c.3236G>A p.G1079E | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100221493; called by muse, mutect2, varscan2
- CACNA1E | c.4366C>T p.L1456F | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62387213; called by muse, mutect2, varscan2
- CACNA1E | c.4769G>A p.G1590D | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100705792; called by muse, mutect2, varscan2
- CACNA1F | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 146/280 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV59903870; called by muse, mutect2, varscan2
- CACNA1H | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 179/560 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs1456584884; called by muse, varscan2
- CACNA2D1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV62372027; called by muse, mutect2, varscan2
- CACNA2D3 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs775717340, COSV55530928; called by muse, mutect2, varscan2
- CACNG3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 110/386 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs868820485, COSV50063824; called by muse, mutect2, varscan2
- CACNG3 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.121); catalogued as rs762148926; called by muse, varscan2
- CALCA | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 102/392 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.835); catalogued as rs1219180885, COSV59028728; called by muse, mutect2, varscan2
- CALD1 | c.2113C>T p.P705S (on ENST00000361675 / NM_033138.4; = p.P450S on NM_004342.7) | Missense Mutation (SNP) | VAF 152/440 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as rs1208094501; called by muse, mutect2, varscan2
- CALHM1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 143/364 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs533171925; called by muse, mutect2, varscan2
- CALHM5 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV62067757; called by muse, mutect2, varscan2
- CAMK4 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56671296; called by muse, mutect2, varscan2
- CAPN13 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs747506933; called by muse, mutect2, varscan2
- CAPN6 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749267304; called by muse, mutect2, varscan2
- CAPSL | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV68438907; called by muse, mutect2
- CAPZA3 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577490193, COSV99856891; called by muse, mutect2, varscan2
- CATSPERB | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as rs752163291; called by muse, varscan2
- CATSPERD | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as rs759789776; called by muse, mutect2, varscan2
- CBLL1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 132/431 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs140545696; called by muse, mutect2, varscan2
- CBX2 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 135/541 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1309025737; called by muse, mutect2, varscan2
- CC2D2B | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038283293; called by muse, mutect2, varscan2
- CCDC105 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV52963305, COSV99479788; called by muse, mutect2, varscan2
- CCDC141 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs868586229; called by muse, mutect2, varscan2
- CCDC168 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1052802593; called by muse, mutect2, varscan2
- CCDC38 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV60183131; called by muse, mutect2, varscan2
- CCDC47 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1466375449; called by muse, mutect2, varscan2
- CCR2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs866454124, COSV52748666; called by muse, mutect2, varscan2
- CD163 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766660196, COSV63131903; called by muse, mutect2, varscan2
- CD163L1 | c.3949G>A p.G1317R | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58016418; called by muse, mutect2, varscan2
- CD163L1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 109/430 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV58021540; called by muse, mutect2, varscan2
- CD38 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as rs1393490181, COSV56889281; called by muse, mutect2, varscan2
- CDC20B | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1270415206; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH10 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs749846087, COSV52576149; called by muse, mutect2, varscan2
- CDH12 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV66454712; called by muse, mutect2, varscan2
- CDH13 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV51804764; called by muse, mutect2, varscan2
- CDH15 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs761243807, COSV57025553; called by muse, mutect2, varscan2
- CDH17 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV50337755; called by muse, mutect2, varscan2
- CDH18 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757870883, COSV56965537, COSV99936187; called by muse, mutect2, varscan2
- CDH4 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922235979; called by muse, mutect2, varscan2
- CDH6 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV54067736, COSV54069315; called by muse, mutect2
- CDH9 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs780971188, COSV50424850, COSV50472197; called by muse, mutect2, varscan2
- CDK20 | c.874C>T p.P292S (on ENST00000325303 / NM_001039803.3; = p.P271S on NM_012119.4) | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972763345; called by muse, varscan2
- CECR2 | c.3773C>T p.S1258L (on ENST00000342247 / NM_001290047.2; = p.S1074L on NM_001290046.1) | Missense Mutation (SNP) | VAF 129/434 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV99378047; called by muse, mutect2, varscan2
- CEL | c.1789C>T p.P597S (on ENST00000673714; = p.P594S on NM_001807.6) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.973); catalogued as COSV99053328; called by muse, mutect2, varscan2
- CELA1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 92/388 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763881505; called by muse, mutect2, varscan2
- CELA1 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 104/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355480488; called by muse, mutect2
- CELF2 | c.484C>T p.R162W (on ENST00000416382 / NM_001025077.3; = p.R169W on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59976707; called by muse, varscan2
- CEP104 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs149976444; called by muse, mutect2, varscan2
- CERS3 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371927785; called by muse, mutect2, varscan2
- CETN1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 135/415 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs1400464859, COSV100511196; called by muse, mutect2, varscan2
- CFAP221 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 70/274 reads (26%) | catalogued as COSV54659789, COSV99732053; called by muse, mutect2, varscan2
- CFAP44 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs1333932921; called by muse, mutect2, varscan2
- CFAP45 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs200089318; called by muse, mutect2, varscan2
- CFAP54 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1430192241; called by muse, mutect2, varscan2
- CFAP54 | c.7828C>T p.L2610F | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV61571396, COSV61571517; called by muse, mutect2, varscan2
- CFAP54 | c.7829T>A p.L2610H | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100733086, COSV61573580; called by muse, mutect2, varscan2
- CFAP61 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs139670332; called by muse, mutect2, varscan2
- CFAP77 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs750950057, COSV58018663; called by muse, mutect2, varscan2
- CFAP91 | c.2170C>T p.L724F | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.563); catalogued as COSV56342833; called by muse, mutect2, varscan2
- CFAP92 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310410191; called by muse, varscan2
- CFAP99 | c.91G>A p.E31K (on ENST00000506607; = p.E516K on NM_001193282.3) | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1212578517; called by muse, mutect2, varscan2
- CFH | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62777470; called by muse, mutect2, varscan2
- CFHR4 | c.668C>T p.S223F (on ENST00000367416 / NM_001201551.2; = p.S224F on NM_001201550.3) | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52225685; called by muse, mutect2, varscan2
- CFHR5 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV56821677; called by muse, mutect2
- CHIA | c.437G>A p.G146E (on ENST00000343320; = p.G38E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58476504; called by muse, mutect2, varscan2
- CHRM2 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57770121; called by muse, mutect2, varscan2
- CHRM4 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 122/481 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV63126213; called by muse, mutect2, varscan2
- CHST1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 96/432 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV57323554; called by muse, mutect2, varscan2
- CHST13 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 154/513 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV60042282; called by muse, mutect2
- CILP | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026724; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN1 | c.2650C>T p.L884F | Missense Mutation (SNP) | VAF 101/482 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1348139848; called by muse, mutect2, varscan2
- CLDN1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs537860492, COSV55044655; called by muse, varscan2
- CLDN14 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as rs756095919; called by muse, mutect2, varscan2
- CLIC2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 97/176 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782270791, COSV58935841; called by muse, mutect2, varscan2
- CMA1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs1235440001; called by muse, mutect2, varscan2
- CMTR2 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57603459; called by muse, mutect2, varscan2
- CNGA2 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 143/250 reads (57%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758699633, COSV61705411; called by muse, mutect2, varscan2
- CNN2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99567588; called by muse, mutect2, varscan2
- CNNM1 | c.2176C>T p.L726= | Splice Region (SNP) | VAF 97/257 reads (38%) | catalogued as rs749240498, COSV63202163; called by muse, mutect2, varscan2
- CNNM3 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1305818270; called by muse, mutect2, varscan2
- CNTNAP2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 91/392 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs201187461, COSV62216314; called by muse, mutect2, varscan2
- CNTNAP3 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV52664256; called by muse, mutect2, varscan2
- COBL | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 147/487 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.388); catalogued as COSV54339682; called by muse, mutect2, varscan2
- COL10A1 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403393545; ClinVar: uncertain significance; called by muse, varscan2
- COL10A1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754330529; called by muse, mutect2, varscan2
- COL11A1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373294721, COSV100617734; called by muse, mutect2, varscan2
- COL12A1 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs780206104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL19A1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 96/383 reads (25%) | catalogued as rs866179157, COSV59586186; called by muse, mutect2, varscan2
- COL19A1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1273072016; called by muse, mutect2, varscan2
- COL1A1 | c.4088C>T p.S1363F | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1343155546; called by muse, mutect2, varscan2
- COL21A1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 89/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55159569; called by muse, mutect2, varscan2
- COL22A1 | c.4348G>A p.G1450R | Missense Mutation (SNP) | VAF 175/358 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477888642, COSV100278503; called by muse, mutect2, varscan2
- COL3A1 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1468768980; called by muse, mutect2, varscan2
- COL4A4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 124/560 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762822768, COSV61633794; called by muse, mutect2, varscan2
- COL4A4 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866282147, COSV61633918; called by muse, mutect2, varscan2
- COL5A1 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs187022757; called by mutect2, varscan2
- COL6A2 | c.1770G>A p.T590= | Splice Region (SNP) | VAF 103/302 reads (34%) | catalogued as rs150999832, COSV100152798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 126/461 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55100859; called by muse, mutect2, varscan2
- COL6A5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55213057; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- COLEC10 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60523251; called by muse, mutect2, varscan2
- COMMD8 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.978); catalogued as rs1466358636, COSV67500322; called by muse, mutect2, varscan2
- COQ9 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1296776586, COSV99345805; called by muse, mutect2, varscan2
- CORIN | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1384275873, COSV56699540; called by muse, mutect2, varscan2
- CPA6 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1043963846, COSV52719988; called by muse, mutect2, varscan2
- CPAMD8 | c.1777C>T p.H593Y (on ENST00000651564; = p.H546Y on NM_015692.5) | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as COSV52237862; called by muse, mutect2, varscan2
- CPB1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs759210795; called by muse, mutect2, varscan2
- CPNE3 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV52204523, COSV99547802; called by muse, mutect2
- CPS1 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs772786711, COSV51819476; called by muse, mutect2, varscan2
- CPSF6 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 137/494 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV57014527; called by muse, mutect2, varscan2
- CPT1C | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV54920627; called by muse, mutect2, varscan2
- CR1L | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV54324849; called by muse, mutect2, varscan2
- CRB1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1389085632, CM160493, COSV66329286; called by muse, mutect2, varscan2
- CRB2 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 184/636 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1362160134; called by muse, mutect2, varscan2
- CREB3L2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 178/567 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759528760; called by muse, mutect2, varscan2
- CRISP2 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100189237; called by muse, varscan2
- CRYBG1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs753275483, COSV64811380; called by muse, varscan2
- CRYBG3 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs933706071; called by muse, mutect2, varscan2
- CSMD1 | c.9874C>T p.L3292F (on ENST00000520002; = p.L3291F on NM_033225.6) | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59297669, COSV59351625; called by muse, mutect2, varscan2
- CSMD2 | c.10082C>T p.S3361L | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs750437715, COSV53885364; called by muse, mutect2, varscan2
- CSMD2 | c.9830C>T p.S3277F | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53935568; called by muse, varscan2
- CSMD2 | c.4133C>T p.S1378L | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV53906670; called by muse, mutect2, varscan2
- CSMD2 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 89/387 reads (23%) | catalogued as COSV53948375; called by muse, varscan2
- CSMD2 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs149094471; called by muse, varscan2
- CSMD2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs781404797, COSV53876686, COSV53911244; called by muse, mutect2, varscan2
- CSMD2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as COSV53887331, COSV99588413; called by muse, mutect2, varscan2
- CSMD3 | c.10390C>T p.P3464S (on ENST00000297405 / NM_001363185.1; = p.P3295S on NM_052900.3) | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141126792, COSV52122184; called by muse, mutect2, varscan2
- CST5 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59015500; called by muse, mutect2, varscan2
- CTDNEP1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs764567346; called by muse, mutect2, varscan2
- CTNNA2 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.401); catalogued as COSV63585783; called by muse, mutect2, varscan2
- CXCR3 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 163/312 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65461879; called by muse, mutect2, varscan2
- CYFIP2 | c.2254C>T p.R752* (on ENST00000616178 / NM_001291722.2; = p.R727* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 77/287 reads (27%) | catalogued as rs1353891660, COSV59044652; called by muse, mutect2, varscan2
- CYP2W1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 101/396 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs199737246; called by muse, mutect2, varscan2
- CYP3A43 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV104412771, COSV55937138; called by muse, mutect2, varscan2
- CYP4F8 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1467728781; called by muse, mutect2, varscan2
- CYTIP | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs763995680, COSV51636381; called by muse, mutect2, varscan2
- DACH1 | c.1984G>A p.E662K (on ENST00000619232 / NM_001366712.1; = p.E408K on NM_004392.6) | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57506585; called by muse, mutect2, varscan2
- DCAF4L1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs973927928, COSV60786385; called by muse, mutect2, varscan2
- DCC | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59094578; called by muse, mutect2, varscan2
- DCC | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs370927048; called by muse, mutect2, varscan2
- DCDC1 | c.4508C>T p.P1503L (on ENST00000597505 / NM_001367979.1; = p.P610L on NM_020869.3) | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1377787177, COSV100338094; called by muse, mutect2, varscan2
- DDHD1 | c.484C>T p.L162F (on ENST00000323669; = p.L359F on NM_030637.3) | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); catalogued as COSV60358073; called by muse, mutect2, varscan2
- DDX60 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 82/366 reads (22%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.868); catalogued as COSV67100439; called by muse, mutect2, varscan2
- DDX60 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 82/351 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101190324; called by muse, mutect2, varscan2
- DDX60L | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52720259; called by muse, mutect2
- DEF6 | c.426G>A p.V142= | Splice Region (SNP) | VAF 58/244 reads (24%) | catalogued as COSV57354958; called by muse, mutect2, varscan2
- DEFA5 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 159/555 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as COSV57962415; called by muse, mutect2, varscan2
- DEFB116 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV68722228; called by muse, mutect2, varscan2
- DEFB125 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 71/234 reads (30%) | catalogued as COSV101217452; called by muse, mutect2, varscan2
- DENND2C | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs368021056, COSV101283898; called by muse, mutect2, varscan2
- DENND6B | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs752611071; called by muse, mutect2, varscan2
- DGKG | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as rs756619637, COSV53966094; called by muse, mutect2, varscan2
- DGLUCY | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 91/377 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV99824105; called by muse, mutect2, varscan2
- DHX36 | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 76/280 reads (27%) | catalogued as COSV57672737; called by muse, mutect2, varscan2
- DHX40 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773521950; called by muse, mutect2, varscan2
- DIABLO | c.98C>T p.A33V (on ENST00000443649 / NM_001278303.1; = p.A106V on NM_019887.6) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928278; called by muse, mutect2, varscan2
- DIS3L2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 72/258 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs745989142, COSV56054679; ClinVar: uncertain significance; called by muse, varscan2
- DISP2 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 148/587 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as rs867264440; called by muse, mutect2, varscan2
- DISP3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 160/529 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV53825748; called by muse, mutect2, varscan2
- DLC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV52305027; called by muse, mutect2, varscan2
- DLGAP2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 171/660 reads (26%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as rs775248738; called by muse, mutect2, varscan2
- DMBT1 | c.2948C>T p.S983L (on ENST00000338354 / NM_001377530.1; = p.S484L on NM_004406.3) | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.728); catalogued as rs368577187; called by muse, mutect2, varscan2
- DMD | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as CM073011; called by muse, mutect2, varscan2
- DMTN | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 103/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760630620; called by muse, mutect2, varscan2
- DNAH10 | c.2983C>T p.R995C (on ENST00000409039; = p.R934C on NM_207437.3) | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757691040, COSV68989857; called by muse, mutect2, varscan2
- DNAH11 | c.11761G>A p.E3921K | Missense Mutation (SNP) | VAF 106/391 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs774963422, COSV60944680; called by muse, mutect2, varscan2
- DNAH11 | c.12041G>A p.R4014K | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV60966113; called by muse, mutect2, varscan2
- DNAH2 | c.5519G>A p.R1840Q | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs762805190, COSV66718172; called by muse, varscan2
- DNAH3 | c.7612G>A p.G2538R | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as rs1054017513, COSV54548719; called by muse, mutect2, varscan2
- DNAH3 | c.6839G>A p.R2280Q | Missense Mutation (SNP) | VAF 79/308 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54506885; called by muse, mutect2, varscan2
- DNAH6 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs954865988; called by muse, mutect2, varscan2
- DNAH6 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52850815; called by muse, varscan2
- DNAH6 | c.6742C>T p.Q2248* | Nonsense Mutation (SNP) | VAF 66/208 reads (32%) | catalogued as rs867541838, COSV99404233; called by muse, varscan2
- DNAH7 | c.9000G>A p.W3000* | Nonsense Mutation (SNP) | VAF 88/327 reads (27%) | catalogued as rs992919354, COSV100416971; called by muse, mutect2, varscan2
- DNAH7 | c.8738G>A p.G2913E | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1203000404, COSV100416123; called by muse, mutect2, varscan2
- DNAH7 | c.6595G>A p.E2199K | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.297); catalogued as rs912644431, COSV56770084; called by muse, mutect2, varscan2
- DNAH7 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1209203569; called by muse, mutect2, varscan2
- DNAJC28 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as rs749152213, COSV58721355; called by muse, mutect2, varscan2
- DNALI1 | c.304G>A p.E102K (on ENST00000296218; = p.E80K on NM_003462.5) | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs568671928; called by muse, mutect2, varscan2
- DNM3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62453504; called by muse, mutect2, varscan2
- DNMT1 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs745753378, COSV61583872; called by muse, mutect2, varscan2
- DOCK3 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56540387; called by muse, varscan2
- DOCK6 | c.3233C>T p.T1078I | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs1418483197, COSV53914305; called by muse, mutect2, varscan2
- DOCK8 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs866349198; called by muse, mutect2, varscan2
- DOK6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66927035; called by muse, varscan2
- DPP10 | c.1977G>A p.M659I | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.374); catalogued as rs1024097964, COSV59714962; called by muse, mutect2, varscan2
- DSC2 | c.354+1G>A p.X118_splice | Splice Site (SNP) | VAF 36/90 reads (40%) | catalogued as rs764016208; called by muse, varscan2
- DSC3 | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs746851464; called by muse, mutect2, varscan2
- DSCAM | c.5519C>T p.S1840L | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68036535; called by muse, mutect2, varscan2
- DSG1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561112685, COSV57133677; called by muse, varscan2
- DUOX2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 121/400 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV66533233; called by muse, mutect2, varscan2
- DYSF | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs758663659, COSV50638852; called by muse, mutect2, varscan2
- DYSF | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs151109021, COSV99249763; called by muse, mutect2, varscan2
- DYSF | c.4823G>A p.G1608E | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV50277075; called by muse, mutect2, varscan2
- E2F8 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs752795277; called by muse, varscan2
- ECE1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51664673; called by muse, mutect2, varscan2
- EDIL3 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56894219; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs951686169, COSV62569495; called by muse, mutect2, varscan2
- EFHB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as COSV55545742; called by muse, mutect2, varscan2
- EGR2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 126/498 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99654167; called by muse, mutect2, varscan2
- EHF | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV57667976; called by muse, mutect2, varscan2
- EIF2AK4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs928627546; called by muse, mutect2, varscan2
- ENAH | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1344761260; called by muse, mutect2, varscan2
- ENC1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs1261044203; called by muse, mutect2, varscan2
- ENPP1 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765071179, CM031968, COSV62930765, COSV62936019; called by muse, mutect2, varscan2
- ENPP4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs1262614085, COSV100320409, COSV58088422; called by muse, mutect2, varscan2
- ENTPD5 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1041514086; called by muse, mutect2, varscan2
- EP400 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1390000729; called by muse, mutect2, varscan2
- EP400 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs769410643; called by muse, mutect2, varscan2
- EPG5 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 113/342 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs747411280, COSV56354954; called by muse, mutect2, varscan2
- EPHA1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1454804041, COSV51969779; called by muse, mutect2, varscan2
- EPHA6 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV67561274; called by muse, mutect2, varscan2
- EPHA6 | c.2293G>A p.D765N (on ENST00000389672 / NM_001080448.3; = p.D157N on NM_173655.4) | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV67559118; called by muse, varscan2
- EPHB2 | c.1735G>A p.D579N (on ENST00000400191 / NM_001309193.2; = p.D580N on NM_004442.7) | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1308309622; called by muse, mutect2, varscan2
- EPHB3 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1194071164; called by muse, mutect2, varscan2
- EPHX4 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482765775, COSV64889083; called by muse, mutect2, varscan2
- EPPK1 | c.5995G>A p.E1999K | Missense Mutation (SNP) | VAF 25/604 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs528153180, COSV99081822; called by muse, mutect2
- EPX | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376090047; called by muse, mutect2, varscan2
- ERBB4 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53532933; called by muse, mutect2, varscan2
- ERC2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 122/419 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs866470365, COSV55609221, COSV55611425; called by muse, mutect2, varscan2
- ERC2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs767117758, COSV55606932; called by muse, mutect2, varscan2
- ERC2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs866429245, COSV55642982; called by muse, mutect2, varscan2
- ERC2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 73/221 reads (33%) | catalogued as COSV55604361; called by muse, mutect2, varscan2
- ERCC4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 78/309 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.177); catalogued as rs768243270; called by muse, mutect2, varscan2
- ERICH3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100443944; called by muse, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2, varscan2
- ERVV-1 | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 160/895 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs1343368725; called by muse, mutect2, varscan2
- EVPL | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs772658064; called by muse, mutect2, varscan2
- EYA4 | c.1254G>A p.M418I (on ENST00000531901 / NM_001301013.1; = p.M412I on NM_004100.5) | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV62046235; called by muse, mutect2, varscan2
- EYS | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs773888841; called by muse, mutect2, varscan2
- EYS | c.3639G>A p.M1213I | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100426357; called by muse, mutect2, varscan2
- EZHIP | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 133/220 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1160395492, COSV99080054; called by muse, mutect2, varscan2
- F13B | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100803324; called by muse, mutect2, varscan2
- F2RL3 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 126/462 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1479410686; called by muse, mutect2, varscan2
- F8 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CD0911163; called by muse, mutect2, varscan2
- F8 | c.3944G>A p.R1315K | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64279622; called by muse, mutect2, varscan2
- FAM120A | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs148997614, COSV99464194; called by muse, mutect2, varscan2
- FAM120A | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52905120; called by muse, mutect2, varscan2
- FAM120A | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 140/512 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.129); catalogued as rs368196789; called by muse, mutect2, varscan2
- FAM124A | c.110C>T p.S37F (on ENST00000322475 / NM_001242312.2; = p.S73F on NM_145019.4) | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV54481053; called by muse, mutect2, varscan2
- FAM153B | c.428C>T p.P143L (on ENST00000253490; = p.P66L on NM_001265615.1) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1448548816; called by mutect2, varscan2
- FAM170A | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs1418317680; called by muse, mutect2, varscan2
- FAM189A1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 120/485 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs990599683; called by muse, mutect2, varscan2
- FAM205A | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 115/339 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1360827261; called by muse, mutect2, varscan2
- FAM209B | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs147485907; called by muse, mutect2, varscan2
- FAM227B | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV54804861; called by muse, mutect2, varscan2
- FAM234A | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 126/393 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56994295; called by muse, mutect2, varscan2
- FAM53C | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 201/652 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs552038703; called by muse, mutect2, varscan2
- FAM71F1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 133/496 reads (27%) | catalogued as COSV100170810, COSV59373509; called by muse, mutect2, varscan2
- FAM83B | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 92/467 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs1397886517, COSV60923578; called by muse, mutect2, varscan2
- FAM90A1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757971003, COSV56711083; called by muse, mutect2, varscan2
- FANCA | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as rs776297241; called by muse, mutect2, varscan2
- FAT1 | c.5315G>A p.G1772E | Missense Mutation (SNP) | VAF 92/405 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499370; called by muse, mutect2, varscan2
- FAT4 | c.12616G>A p.D4206N | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.991); catalogued as rs1388508781; called by muse, mutect2, varscan2
- FAT4 | c.13382G>A p.G4461E | Missense Mutation (SNP) | VAF 122/453 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58677892; called by muse, mutect2, varscan2
- FBH1 | c.377C>T p.S126F (on ENST00000362091 / NM_178150.3; = p.S177F on NM_032807.4) | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.259); catalogued as rs1211229439; called by muse, mutect2, varscan2
- FBLN2 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372540399; called by muse, mutect2, varscan2
- FBN2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52512377, COSV99326305; called by muse, mutect2, varscan2
- FBN2 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs149305476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL19 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1373318151; called by muse, mutect2, varscan2
- FBXO15 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99503998; called by muse, mutect2, varscan2
- FBXO41 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 114/442 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as rs1371318436; called by muse, mutect2, varscan2
- FBXW10 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57320894; called by muse, mutect2, varscan2
- FCAMR | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV61367167; called by muse, mutect2, varscan2
- FCAMR | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.86); catalogued as COSV100249793, COSV61367808; called by muse, mutect2, varscan2
- FCGR2A | c.485C>T p.S162F (on ENST00000271450 / NM_001136219.3; = p.S161F on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV54837374; called by muse, mutect2, varscan2
- FCN3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 133/356 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs753804930; called by muse, mutect2, varscan2
- FCRL1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs781633537; called by muse, mutect2, varscan2
- FCRL6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs866572573; called by muse, mutect2, varscan2
- FDCSP | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.458); catalogued as rs768557922, COSV58764779, COSV58765221; called by muse, mutect2, varscan2
- FER1L6 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV67553020; called by muse, mutect2, varscan2
- FERMT1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1257287311; called by muse, mutect2, varscan2
- FGD5 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.142); catalogued as COSV53255037; called by muse, mutect2, varscan2
- FGF12 | c.563G>A p.R188K (on ENST00000454309 / NM_021032.5; = p.R126K on NM_004113.6) | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV53151914, COSV53164870; called by muse, mutect2, varscan2
- FGL2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 91/398 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.403); catalogued as rs763617359, COSV50381062; called by muse, mutect2, varscan2
- FIBIN | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 129/462 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); catalogued as rs771433235, COSV100590477; called by muse, mutect2, varscan2
- FLG | c.10747G>A p.E3583K | Missense Mutation (SNP) | VAF 107/567 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as rs144652887; called by muse, mutect2, varscan2
- FLG | c.10331G>A p.G3444E | Missense Mutation (SNP) | VAF 96/508 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV64242156; called by muse, mutect2, varscan2
- FLT1 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.39); catalogued as rs41291686; called by muse, mutect2, varscan2
- FLT4 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.184); catalogued as COSV56107947; called by muse, mutect2, varscan2
- FLYWCH1 | c.550C>T p.R184W (on ENST00000253928 / NM_001308068.2; = p.R183W on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/587 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs534891725; called by muse, mutect2, varscan2
- FNDC7 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs769004072, COSV54750530; called by muse, mutect2, varscan2
- FOXA3 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 163/509 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs758978324, COSV100141529; called by muse, mutect2, varscan2
- FOXI2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs900236763; called by muse, mutect2, varscan2
- FOXJ1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 167/575 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs764881454; called by muse, mutect2, varscan2
- FPR1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs754643538, COSV59053722; called by muse, varscan2
- FPR3 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59329981; called by muse, mutect2, varscan2
- FRAS1 | c.7205C>T p.T2402I | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV53606776; called by muse, mutect2, varscan2
- FREM1 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 206/308 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199731115; called by muse, mutect2, varscan2
- FREM2 | c.4104G>A p.M1368I | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54853304; called by muse, mutect2, varscan2
- FREM2 | c.7115C>T p.P2372L | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54851481; called by muse, mutect2, varscan2
- FREM3 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1158677305; called by muse, mutect2, varscan2
- FRMPD2 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs142425834; called by muse, mutect2, varscan2
- FSCB | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV61218053; called by muse, mutect2, varscan2
- FSD1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 113/425 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV99696614; called by muse, varscan2
- FSIP2 | c.7362G>A p.M2454I | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV58085277; called by muse, mutect2, varscan2
- FUT9 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as COSV56153225; called by muse, mutect2, varscan2
- FYB1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1019736755; called by muse, mutect2, varscan2
- FYB2 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs767925458, COSV58585039; called by muse, varscan2
- FYB2 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 192/494 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs1321251035, COSV58583992; called by muse, mutect2, varscan2
- FYB2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs1339826336; called by muse, mutect2, varscan2
- GABBR2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1046552015, COSV52306815; called by muse, mutect2, varscan2
- GABRA2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62915135; called by muse, mutect2, varscan2
- GABRA4 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 121/403 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.183); catalogued as COSV99974304; called by muse, mutect2, varscan2
- GABRD | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs758230164; called by muse, mutect2, varscan2
- GABRE | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 159/266 reads (60%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64818966; called by muse, mutect2, varscan2
- GALR1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs267605260; called by muse, varscan2
- GCNT3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 111/390 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV68532082; called by muse, mutect2, varscan2
- GDPD2 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65533653; called by muse, mutect2, varscan2
- GFOD2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 131/429 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs774607823; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, mutect2, varscan2
- GFRAL | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 66/382 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV61228927; called by muse, varscan2
- GIMAP8 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1228260931, COSV56229803; called by muse, mutect2, varscan2
- GJB5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs373605298; called by muse, mutect2, varscan2
- GK2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1225278704, COSV100725968, COSV62627961; called by muse, mutect2, varscan2
- GK3P | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765877205; called by muse, mutect2, varscan2
- GLDN | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091151; called by muse, mutect2, varscan2
- GLE1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 106/385 reads (28%) | catalogued as rs772765696, COSV100012594; called by muse, mutect2, varscan2
- GLIS2 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 196/728 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs774339298; called by muse, mutect2, varscan2
- GLIS3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as rs746113432; called by muse, mutect2, varscan2
- GLYATL2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54848971; called by muse, mutect2, varscan2
- GLYATL3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 126/605 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203373752, COSV64591840; called by muse, mutect2, varscan2
- GPA33 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs376774161; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR158 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs776684937; called by muse, mutect2, varscan2
- GPR183 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1223881941, COSV63118103; called by muse, mutect2, varscan2
- GPR52 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170872463, COSV52308291; called by muse, mutect2, varscan2
- GRAMD1A | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs371582697; called by muse, mutect2, varscan2
- GRIA1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV53616525; called by muse, mutect2
- GRID2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 127/446 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56173140; called by muse, mutect2, varscan2
- GRID2IP | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1437768925, COSV70693370; called by muse, mutect2, varscan2
- GRIK2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV59715122; called by muse, mutect2, varscan2
- GRIK2 | c.1766G>A p.W589* | Nonsense Mutation (SNP) | VAF 51/224 reads (23%) | catalogued as COSV59775824; called by muse, mutect2, varscan2
- GRIN2A | c.4180C>T p.Q1394* | Nonsense Mutation (SNP) | VAF 120/426 reads (28%) | catalogued as rs1555482011; called by muse, mutect2, varscan2
- GRIN2A | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58033008; called by muse, mutect2, varscan2
- GRIN2A | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 115/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766162952, COSV58019482; called by muse, mutect2, varscan2
- GRIN3A | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 102/467 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1369474596; called by muse, mutect2
- GRIP1 | c.1489C>T p.L497F (on ENST00000359742 / NM_001379345.1; = p.L445F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54037623; called by muse, mutect2, varscan2
- GRIP1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54018884; called by muse, mutect2, varscan2
- GRK2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as rs200019576, COSV57952168; called by muse, mutect2, varscan2
- GRM4 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 133/610 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.762); catalogued as rs372962596; called by muse, mutect2, varscan2
- GRM7 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 110/248 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs753302178, COSV100737974; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 108/415 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- GSTT2B | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs1363192467; called by mutect2, varscan2
- GTF2H3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.056); catalogued as COSV57458424; called by muse, mutect2, varscan2
- GUCY2C | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 105/347 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV53791042; called by muse, mutect2, varscan2
- GUCY2D | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751520851; called by muse, mutect2, varscan2
- GYG2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 132/237 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs769801910; called by muse, mutect2, varscan2
- GYS2 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53922336; called by muse, mutect2, varscan2
- GZMK | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140814; called by muse, mutect2, varscan2
- H2AC1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs778464441, COSV51237673; called by muse, mutect2, varscan2
- H2BC13 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 176/413 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.397); catalogued as rs1296867144, COSV62440493, COSV62441170; called by muse, mutect2, varscan2
- HAVCR2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 86/354 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57152484; called by muse, mutect2, varscan2
- HCK | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52944634; called by muse, mutect2, varscan2
- HCN3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs761642949, COSV64234068; called by muse, mutect2, varscan2
- HCRTR2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63795703; called by muse, mutect2, varscan2
- HDAC9 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV67778618; called by muse, mutect2, varscan2
- HEPACAM | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 156/389 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs942489824, COSV53429749; called by muse, mutect2, varscan2
- HEPHL1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59889199, COSV59897729; called by muse, mutect2, varscan2
- HEPHL1 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs939355851, COSV59889696; called by muse, mutect2, varscan2
- HHATL | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs763678611; called by muse, mutect2, varscan2
- HHLA1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51842324; called by muse, mutect2, varscan2
- HHLA2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 111/483 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as rs201761554, COSV63316858; called by muse, mutect2, varscan2
- HLF | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 118/462 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56828912; called by muse, mutect2, varscan2
- HMG20B | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774881413; called by muse, mutect2, varscan2
- HMGCLL1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs373359419; called by muse, mutect2, varscan2
- HNF1A | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 123/447 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV57462521; called by muse, mutect2, varscan2
- HNRNPCL2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 210/578 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs767315185, COSV60402218; called by muse, varscan2
- HP | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs868021678; called by muse, mutect2, varscan2
- HP | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63326139; called by muse, mutect2, varscan2
- HS3ST1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 79/364 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs368275390; called by muse, mutect2, varscan2
- HS3ST4 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58817016, COSV58824926; called by muse, mutect2, varscan2
- HSD3B1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 129/567 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV52491891; called by muse, mutect2, varscan2
- HSH2D | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV53736856; called by muse, mutect2, varscan2
- HTR3E | c.832C>T p.R278C (on ENST00000415389 / NM_001256613.1; = p.R293C on NM_182589.2) | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs746823917, COSV58946547; called by muse, mutect2, varscan2
- HTR3E | c.1102G>A p.E368K (on ENST00000415389 / NM_001256613.1; = p.E383K on NM_182589.2) | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV58945796; called by mutect2, varscan2
- HYDIN | c.12094G>A p.E4032K | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs764047434; called by muse, mutect2, varscan2
- HYDIN | c.8327G>A p.G2776E | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99992637; called by muse, mutect2, varscan2
- HYDIN | c.6286G>A p.E2096K | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs748365700; called by muse, varscan2
- IARS1 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986882, COSV65115288; called by muse, mutect2, varscan2
- IARS2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56957822; called by muse, mutect2, varscan2
- IFFO1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 116/461 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1005038965, COSV100350979; called by muse, mutect2, varscan2
- IGDCC3 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 104/423 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs749012028; called by muse, mutect2, varscan2
- IGF2BP1 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs771227164, COSV51735129; called by muse, mutect2, varscan2
- IGFBP2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs759413522, COSV99288284; called by muse, varscan2
- IGHM | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.497); catalogued as rs782021270; called by muse, mutect2, varscan2
- IGHV3-16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782709611; called by muse, varscan2
- IGLV1-50 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as rs759700968; called by muse, mutect2, varscan2
- IGSF22 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 90/364 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140962677, COSV60036734; called by muse, varscan2
- IKBIP | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 80/361 reads (22%) | catalogued as rs1239346339, COSV61081677; called by muse, mutect2, varscan2
- IKZF1 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58786076; called by muse, mutect2, varscan2
- IL16 | c.2780G>C p.R927P (on ENST00000302987 / NM_172217.5; = p.R226P on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/600 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as rs750738616, COSV57260733; called by muse, mutect2, varscan2
- IL1RN | c.520C>T p.Q174* (on ENST00000409930 / NM_173842.3; = p.Q156* on NM_000577.5) | Nonsense Mutation (SNP) | VAF 76/289 reads (26%) | catalogued as rs1194548751; called by muse, mutect2, varscan2
- IL2RB | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1247021813; called by muse, mutect2, varscan2
- IL37 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV54492279; called by muse, mutect2, varscan2
- ILDR1 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 117/408 reads (29%) | catalogued as rs1278668451; called by muse, mutect2, varscan2
- ILDR2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54834429; called by muse, mutect2, varscan2
- INAVA | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 120/336 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1232228678; called by muse, mutect2, varscan2
- INPPL1 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775327646; called by muse, mutect2, varscan2
- INSRR | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1281379240; called by muse, mutect2, varscan2
- INSYN2B | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 74/279 reads (27%) | catalogued as COSV56944832; called by muse, mutect2, varscan2
- INTS1 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748233239; called by muse, mutect2, varscan2
- INTS13 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 125/409 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs71452030; called by muse, mutect2, varscan2
- IRAG2 | c.3547C>T p.L1183F (on ENST00000636465; = p.L228F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/436 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63138820; called by muse, mutect2, varscan2
- IRAG2 | c.3665G>A p.R1222K (on ENST00000636465; = p.R267K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/438 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367987808, COSV100611891; called by muse, mutect2, varscan2
- IRF5 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs760492792; called by muse, mutect2, varscan2
- IRF5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs200486000; called by muse, varscan2
- ISX | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 160/466 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV58088463; called by muse, varscan2
- ITGA4 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV67899245; called by muse, mutect2, varscan2
- ITGA5 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 99/372 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1199065438; called by muse, mutect2, varscan2
- ITGB1BP1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 58/320 reads (18%) | catalogued as rs746882210, COSV53005428; called by muse, mutect2, varscan2
- ITGB2 | c.1132C>T p.H378Y (on ENST00000302347; = p.H354Y on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs952577888; called by muse, mutect2, varscan2
- ITGB4 | c.3490C>T p.Q1164* | Nonsense Mutation (SNP) | VAF 80/304 reads (26%) | catalogued as COSV52330603; called by muse, mutect2, varscan2
- ITIH2 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs538003328, COSV64432053; called by muse, mutect2, varscan2
- ITIH4 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 131/465 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.463); catalogued as rs868637301; called by muse, mutect2, varscan2
- ITIH5 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 112/406 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.044); catalogued as COSV99903895; called by muse, mutect2, varscan2
- ITIH6 | c.3178G>T p.G1060* | Nonsense Mutation (SNP) | VAF 126/227 reads (56%) | catalogued as COSV54489521; called by muse, mutect2, varscan2
- ITPR2 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs773730966, COSV67264269; called by muse, mutect2, varscan2
- ITPR3 | c.6127G>A p.E2043K | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as rs1426384988; called by muse, mutect2, varscan2
- IYD | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.332); catalogued as rs758276873; called by muse, mutect2, varscan2
- JAG1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 150/488 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs745324562, COSV54757872; called by muse, mutect2, varscan2
- JAKMIP1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1174209109, COSV51524627; called by muse, mutect2, varscan2
- JCAD | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64762157; called by muse, mutect2, varscan2
- KANK2 | c.1475C>T p.P492L (on ENST00000586659 / NM_001379562.1; = p.P500L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100763437; called by muse, mutect2, varscan2
- KANK3 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 154/526 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs751134473; called by muse, mutect2, varscan2
- KANK4 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62986323; called by muse, mutect2, varscan2
- KANK4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 116/495 reads (23%) | catalogued as rs1311359487, COSV62985750; called by muse, varscan2
- KBTBD13 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 146/578 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs751061929; called by muse, mutect2, varscan2
- KCNA4 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60252610; called by muse, mutect2, varscan2
- KCNA5 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 116/472 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52903978; called by muse, mutect2, varscan2
- KCNA7 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs762119570, COSV55503557; called by muse, mutect2, varscan2
- KCNH7 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs764152829; called by muse, mutect2, varscan2
- KCNJ2 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV54662329; called by muse, mutect2, varscan2
- KCNK1 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs770054172, COSV100785659; called by muse, mutect2, varscan2
- KCNK5 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 57/308 reads (19%) | catalogued as COSV100851755; called by muse, mutect2, varscan2
- KCNMA1 | c.3608G>A p.S1203N (on ENST00000286628 / NM_001161352.2; = p.S1145N on NM_002247.4) | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV54272952; called by muse, mutect2, varscan2
- KCNMA1 | c.3319G>A p.D1107N (on ENST00000286628 / NM_001161352.2; = p.D1049N on NM_002247.4) | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1314238418, COSV54278061; called by muse, mutect2, varscan2
- KCNQ3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149104914; called by muse, mutect2, varscan2
- KCNQ5 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1428134635; called by muse, mutect2, varscan2
- KCNT1 | c.2167G>A p.E723K (on ENST00000488444; = p.E742K on NM_020822.3) | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749302270, COSV53706134, COSV53708398; called by muse, mutect2, varscan2
- KCNT2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267598261, COSV54073484; called by muse, mutect2
- KCTD15 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 157/552 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52288706; called by muse, mutect2, varscan2
- KCTD16 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as COSV72581028; called by mutect2, varscan2
- KCTD3 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52068212; called by muse, mutect2, varscan2
- KCTD7 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 113/465 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV51877784; called by muse, mutect2, varscan2
- KCTD8 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 129/415 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63584894; called by muse, mutect2, varscan2
- KDELR2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 100/406 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs767483500; called by muse, mutect2, varscan2
- KDM4F | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1277140142; called by muse, mutect2, varscan2
- KERA | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57131174; called by muse, mutect2, varscan2
- KHDRBS2 | c.222C>T p.F74= | Splice Region (SNP) | VAF 48/205 reads (23%) | catalogued as rs914737061; called by muse, mutect2, varscan2
- KIAA0232 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.982); catalogued as COSV100300240; called by muse, mutect2, varscan2
- KIAA1217 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV64601020; called by muse, mutect2, varscan2
- KIF18A | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs754478344; called by muse, mutect2, varscan2
- KIF19 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs757556936; called by muse, mutect2, varscan2
- KIF26A | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV59465761; called by muse, mutect2, varscan2
- KIF26A | c.4829C>T p.P1610L | Missense Mutation (SNP) | VAF 165/628 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1049374160; called by muse, mutect2, varscan2
- KIF4B | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 149/492 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1179198998, COSV70530379, COSV70531050; called by muse, mutect2, varscan2
- KIF4B | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 145/531 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV70531242; called by muse, mutect2, varscan2
- KIF5A | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 125/430 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs764612223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5B | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs760268366, COSV100191333; called by muse, mutect2, varscan2
- KIF5C | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1456311400, COSV68480036; called by muse, varscan2
- KITLG | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57204738; called by muse, mutect2, varscan2
- KLF5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100890594, COSV66615042; called by muse, mutect2, varscan2
- KLHDC7A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 123/536 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1268353271, COSV101272841; called by muse, mutect2, varscan2
- KLRC1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 123/404 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV61724827, COSV61726161; called by muse, mutect2, varscan2
- KMT2D | c.8681C>T p.P2894L | Missense Mutation (SNP) | VAF 101/456 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs771221036, COSV56431356; called by muse, mutect2, varscan2
- KMT2D | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 124/467 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99980141; called by muse, mutect2, varscan2
- KNG1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs377271899, COSV53977396; called by muse, mutect2, varscan2
- KPRP | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV64223102; called by muse, mutect2, varscan2
- KRBA1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 157/560 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55440998; called by muse, mutect2, varscan2
- KRBA1 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 145/517 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.757); catalogued as rs759806968; called by muse, mutect2, varscan2
- KREMEN2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 168/574 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs1342798007; called by muse, mutect2, varscan2
- KRT4 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 121/496 reads (24%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.336); catalogued as COSV99542523; called by muse, mutect2, varscan2
- KRT6B | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 103/479 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV99360961; called by muse, mutect2, varscan2
- KRT72 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 139/540 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs767110728; called by muse, mutect2, varscan2
- KRTAP5-10 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV64794097; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- LACRT | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 123/453 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); catalogued as COSV57688668, COSV57688809; called by muse, mutect2, varscan2
- LAMA1 | c.7181G>A p.R2394Q | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140792199; called by muse, mutect2, varscan2
- LAMA1 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751763826; called by muse, mutect2, varscan2
- LAMA2 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV101370815; called by muse, mutect2, varscan2
- LAMA3 | c.1975G>A p.G659S | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV58072386; called by muse, mutect2, varscan2
- LAMA3 | c.8593G>A p.D2865N (on ENST00000313654 / NM_198129.4; = p.D1256N on NM_000227.6) | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748969259; called by muse, mutect2, varscan2
- LAMB1 | c.3016G>A p.G1006R | Missense Mutation (SNP) | VAF 97/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753339381; called by muse, mutect2, varscan2
- LAMB3 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs746810833, COSV61919274; called by muse, mutect2, varscan2
- LAMB3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs145575474, COSV61916499, COSV61918706; called by muse, mutect2, varscan2
- LAMC3 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 138/525 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs756888738; called by muse, mutect2, varscan2
- LARS2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs993142041, COSV99647844; called by muse, mutect2, varscan2
- LARS2 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748873353, COSV99648397; called by muse, mutect2, varscan2
- LATS1 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99486605; called by muse, mutect2, varscan2
- LBHD1 | c.43A>T p.T15S | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100649260; called by muse, mutect2, varscan2
- LBHD1 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 112/337 reads (33%) | catalogued as rs141627882; called by muse, mutect2, varscan2
- LCTL | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 97/375 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV58422534; called by muse, mutect2, varscan2
- LGR5 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57001780; called by muse, mutect2, varscan2
- LHX9 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61327318; called by muse, mutect2, varscan2
- LIAS | c.580C>T p.R194C (on ENST00000261434 / NM_001363700.2; = p.R297C on NM_006859.4) | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54695422; called by muse, mutect2, varscan2
- LIFR | c.1930C>T p.L644F | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54690666, COSV54699507; called by muse, mutect2, varscan2
- LILRA5 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs749404393, COSV56641374, COSV56643986; called by muse, mutect2, varscan2
- LILRB1 | c.1640G>A p.R547K (on ENST00000427581; = p.R497K on NM_006669.6) | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.075); catalogued as COSV100207040; called by muse, mutect2, varscan2
- LILRB3 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 132/1064 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1223421126; called by muse, mutect2, varscan2
- LIN28A | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 119/517 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54263179; called by muse, mutect2, varscan2
- LLGL1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780035374; called by muse, mutect2, varscan2
- LNX1 | c.733G>A p.D245N (on ENST00000263925 / NM_001126328.3; = p.D149N on NM_032622.2) | Missense Mutation (SNP) | VAF 106/362 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV99820358; called by muse, mutect2, varscan2
- LONRF3 | c.1613G>A p.R538Q (on ENST00000371628 / NM_001031855.3; = p.R497Q on NM_024778.5) | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339427483; called by muse, mutect2, varscan2
- LOXHD1 | c.6563G>A p.R2188Q (on ENST00000642948; = p.R2126Q on NM_144612.7) | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs748082132, COSV56066575; called by muse, mutect2, varscan2
- LOXHD1 | c.6131G>A p.R2044Q (on ENST00000642948; = p.R1982Q on NM_144612.7) | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs369257983; called by muse, mutect2, varscan2
- LPAR1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs80279284; called by muse, mutect2, varscan2
- LPO | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs1470525499; called by muse, mutect2, varscan2
- LRCH4 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99575046; called by muse, mutect2, varscan2
- LRGUK | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs35862526; called by muse, mutect2, varscan2
- LRP1B | c.10609G>A p.D3537N | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs981984032, COSV67217000; called by muse, varscan2
- LRP1B | c.10002G>A p.W3334* | Nonsense Mutation (SNP) | VAF 70/239 reads (29%) | catalogued as rs868299950, COSV67210054, COSV67254956; called by muse, mutect2, varscan2
- LRP1B | c.9583C>T p.H3195Y | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV101253763, COSV67191721; called by muse, mutect2, varscan2
- LRP1B | c.7813C>T p.P2605S | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as COSV67287587; called by muse, mutect2, varscan2
- LRP1B | c.6512C>T p.A2171V | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101255382, COSV67228796; called by muse, mutect2, varscan2
- LRP1B | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67204342; called by muse, mutect2, varscan2
- LRP2 | c.11894G>A p.G3965E | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55539010; called by muse, mutect2, varscan2
- LRRC3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs865841768, COSV67520179, COSV67522722; called by muse, mutect2, varscan2
- LRRC49 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs1450128270, COSV53008314; called by muse, varscan2
- LRRC9 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs1404603402, COSV54291666; called by muse, mutect2, varscan2
- LRRIQ1 | c.3514C>T p.R1172* | Nonsense Mutation (SNP) | VAF 93/291 reads (32%) | catalogued as rs148400374; called by muse, mutect2, varscan2
- LRRIQ4 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV52979418; called by muse, mutect2, varscan2
- LRRN1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV60012583; called by muse, mutect2
- LRTM2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 105/395 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs778057455; called by muse, mutect2, varscan2
- LTBP2 | c.4588G>A p.D1530N | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs751665600; called by muse, varscan2
- LTBP2 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs757740990; called by muse, mutect2, varscan2
- LUZP1 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 111/442 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1325668649; called by muse, mutect2, varscan2
- LY75 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV55112789, COSV99716211; called by muse, mutect2, varscan2
- LZTR1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV53146362, COSV53149690; called by muse, mutect2, varscan2
- MACC1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs749712233, COSV100256366; called by muse, mutect2, varscan2
- MACC1 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs750519192, COSV100256435; called by muse, mutect2, varscan2
- MACF1 | c.4561C>T p.L1521F | Missense Mutation (SNP) | VAF 145/511 reads (28%) | catalogued as COSV99245210; called by muse, mutect2, varscan2
- MAGEB10 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 138/234 reads (59%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.846); catalogued as rs748209592; called by muse, mutect2, varscan2
- MAGEC1 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV53577923, COSV53580970; called by muse, mutect2, varscan2
- MAGEC1 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs771616249; called by muse, mutect2, varscan2
- MAGEC3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 113/248 reads (46%) | catalogued as rs1210749310, COSV53575606; called by muse, mutect2, varscan2
- MAN1A1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 50/231 reads (22%) | catalogued as rs756590673, COSV63788820; called by muse, mutect2, varscan2
- MAN2A1 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV54846840; called by muse, mutect2, varscan2
- MAP1A | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765277558, COSV55805875; called by muse, varscan2
- MAP3K20 | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1322838259; called by muse, mutect2, varscan2
- MAP3K4 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs746224218, COSV62335380; called by muse, mutect2, varscan2
- MAPK1IP1L | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.979); catalogued as rs1039840270; called by muse, mutect2, varscan2
- MARCO | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779452172, COSV59052856; called by muse, mutect2, varscan2
- MCM2 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766855733; called by muse, mutect2, varscan2
- MCM3AP | c.3169C>T p.L1057F | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771684934; called by muse, mutect2, varscan2
- MCM6 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs372387401; called by muse, mutect2, varscan2
- ME3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.035); catalogued as rs1469175295; called by muse, mutect2, varscan2
- MELTF | c.1332G>A p.P444= | Splice Region (SNP) | VAF 95/318 reads (30%) | catalogued as rs774892741, COSV56382700, COSV99586056; called by muse, mutect2, varscan2
- MET | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs756031094, COSV100577257, COSV59261930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFAP5 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs779901395; called by muse, mutect2, varscan2
- MFHAS1 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 150/548 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1432395986; called by muse, mutect2, varscan2
- MGAM | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs146995745, COSV101516395, COSV71885376; called by muse, mutect2, varscan2
- MGAM2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.022); catalogued as rs559963400; called by muse, mutect2, varscan2
- MIA3 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60509668; called by muse, mutect2, varscan2
- MICA | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 186/507 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101319736; called by muse, mutect2, varscan2
- MLIP | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs866759877; called by muse, mutect2, varscan2
- MMD2 | c.577G>A p.G193S (on ENST00000404774 / NM_001100600.2; = p.G169S on NM_198403.4) | Missense Mutation (SNP) | VAF 118/448 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347814462; called by muse, mutect2, varscan2
- MME | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708482; called by muse, mutect2, varscan2
- MMP26 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs746261222, COSV56171975; called by muse, mutect2, varscan2
- MNDA | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs867226822, COSV63740382; called by muse, mutect2, varscan2
- MNDA | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100933235; called by muse, mutect2, varscan2
- MOG | c.385T>C p.F129L | Missense Mutation (SNP) | VAF 132/614 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1405616065; called by muse, varscan2
- MORC1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as rs746239411, COSV51717426, COSV51725283; called by muse, mutect2, varscan2
- MORC2 | c.1892C>T p.S631F (on ENST00000397641 / NM_001303256.3; = p.S569F on NM_014941.3) | Missense Mutation (SNP) | VAF 142/495 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1218394103; called by muse, mutect2, varscan2
- MPHOSPH8 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs776052318; called by muse, mutect2, varscan2
- MPP7 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100517142; called by muse, mutect2, varscan2
- MRAP | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 71/436 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100353249; called by muse, mutect2, varscan2
- MRGPRX2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV61674009, COSV61674606; called by muse, mutect2, varscan2
- MRO | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 123/400 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.942); catalogued as rs763091240, COSV56496809; called by muse, mutect2, varscan2
- MROH2B | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1471508893; called by muse, mutect2, varscan2
- MROH9 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV100882924; called by muse, mutect2, varscan2
- MRPL45 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1191293963; called by muse, mutect2, varscan2
- MRPS12 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 98/357 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150096976, COSV55500462; called by muse, mutect2, varscan2
- MSR1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50535798; called by muse, mutect2, varscan2
- MST1R | c.3500G>A p.G1167D | Missense Mutation (SNP) | VAF 85/390 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56565716; called by muse, mutect2, varscan2
- MTMR4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs201265445; called by muse, mutect2, varscan2
- MTOR | c.7528G>A p.G2510S | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1412063637; called by muse, mutect2, varscan2
- MUC12 | c.10271C>T p.P3424L (on ENST00000379442; = p.P3281L on NM_001164462.1) | Missense Mutation (SNP) | VAF 257/3694 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1426693122; called by muse, mutect2
3,678 further variants in this file (2,025 protein-altering or splice-affecting, 1,474 silent, 179 other) are not listed here.
